Somatic mutation profile of tumor specimen TCGA-AA-A02J-01A (aliquot TCGA-AA-A02J-01A-01W-A00E-09) from TCGA case TCGA-AA-A02J, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.5 years (25,749 days).
Specimen TCGA-AA-A02J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294bb120-7c08-46b5-9d5c-1eed88ff5c9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02J-10A (Blood Derived Normal), aliquot TCGA-AA-A02J-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25f0080b-d550-4e16-849d-546cd06ac3a0

The open-access MAF lists 133 somatic variants for this specimen: 99 protein-altering or splice-affecting, 29 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 29, Frame Shift Ins 4, Nonsense Mutation 4, Intron 3, Splice Site 2, RNA 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2
- PEX1 | c.1927dup p.T643Nfs*21 | Frame Shift Ins (INS) | VAF 45/211 reads (21%) | catalogued as rs1554372180; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.404G>C p.C135S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52675774, COSV52680475, COSV52702460, COSV53452020; called by muse, mutect2, varscan2
- UNC80 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs864321623, CM160381, COSV55897846; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.843T>C p.G281= | Splice Region (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52948716; called by muse, mutect2, varscan2
- AC004593.2 | c.1482C>G p.D494E | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56088072, COSV56099974; called by muse, mutect2, varscan2
- ACSS2 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 32/1010 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99404534; called by muse, mutect2
- ADAMTS2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1336113069, COSV51098715; called by muse, mutect2
- ADGRG4 | c.4228G>A p.G1410S | Missense Mutation (SNP) | VAF 214/665 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1569323802, COSV54964731; called by muse, mutect2, varscan2
- ADGRV1 | c.11908T>C p.S3970P | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs777156085; called by muse, mutect2, varscan2
- AGTPBP1 | c.3565G>A p.A1189T (on ENST00000357081 / NM_001330701.2; = p.A1149T on NM_015239.2) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as COSV61276297; called by muse, mutect2, varscan2
- APC | c.4142dup p.L1382Tfs*4 | Frame Shift Ins (INS) | VAF 59/181 reads (33%) | catalogued as COSV57392488; called by mutect2, pindel, varscan2
- APC | c.5279C>G p.P1760R | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs562142144, COSV57374211; called by muse, mutect2, varscan2
- ARV1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as COSV59618616; called by muse, mutect2, varscan2
- ASZ1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52915691; called by muse, mutect2, varscan2
- BBS5 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV54753136, COSV54754044; called by muse, mutect2, varscan2
- CARMIL3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs780195306, COSV57728052; called by muse, mutect2
- CDC42BPA | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62018573; called by muse, mutect2, varscan2
- CDH18 | c.721A>C p.M241L | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56953886; called by muse, mutect2, varscan2
- CEACAM5 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs782511943; called by muse, mutect2
- CLSPN | c.2747C>T p.T916I | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs751115510, COSV52056265; called by muse, mutect2, varscan2
- COL28A1 | c.3116C>T p.T1039M | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as rs184264025, COSV68084133; called by muse, mutect2, varscan2
- COL4A4 | c.1225C>G p.P409A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.223); catalogued as COSV61635743; called by muse, mutect2, varscan2
- CSMD2 | c.7367G>A p.R2456Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs867709818, COSV53952924; called by muse, mutect2, varscan2
- CTLA4 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV55593043; called by muse, mutect2, varscan2
- CUL4B | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as COSV60690560; called by muse, mutect2, varscan2
- DCAF8 | c.197G>C p.G66A | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58785622; called by muse, mutect2, varscan2
- DCTD | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63867207; called by muse, mutect2, varscan2
- DDX42 | c.2578G>A p.G860R | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.559); catalogued as rs146221475; called by muse, mutect2, varscan2
- DOCK3 | c.4340G>A p.R1447H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs1560494524, COSV56545156; called by muse, mutect2, varscan2
- EXOC8 | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV50479339; called by muse, mutect2, varscan2
- EZH1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.368); catalogued as COSV70550451; called by muse, mutect2, varscan2
- FBXO36 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV52280581; called by muse, mutect2, varscan2
- FNDC1 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1283200757, COSV51933577; called by muse, mutect2, varscan2
- FNIP2 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52444611; called by muse, mutect2
- FNIP2 | c.192T>G p.F64L | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52444623; called by muse, mutect2
- FOXM1 | c.913G>C p.V305L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV61207319; called by muse, mutect2, varscan2
- GGH | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV52651750; called by muse, mutect2, varscan2
- GRIA3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52077182; called by muse, mutect2, varscan2
- GUCY1B1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs761059016, COSV52375068; called by muse, mutect2, varscan2
- HMCN1 | c.5894C>T p.T1965I | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as COSV54902020; called by muse, mutect2, varscan2
- IARS2 | c.625A>G p.N209D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368937943; called by muse, mutect2, varscan2
- IFNA21 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 107/310 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV66518726; called by muse, mutect2, varscan2
- IPO13 | c.2510C>A p.S837Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV54838430; called by muse, mutect2, varscan2
- ITGA5 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762335174, COSV53219693; called by muse, mutect2, varscan2
- KRT78 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs200710984, COSV58853269; called by muse, mutect2, varscan2
- LRRIQ1 | c.804T>G p.F268L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV67837114; called by muse, mutect2, varscan2
- MGAM | c.3726G>T p.W1242C | Missense Mutation (SNP) | VAF 34/710 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075636; called by muse, mutect2
- MIB1 | c.2701C>T p.R901* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs369135845; called by muse, mutect2, varscan2
- MLH1 | c.2108A>C p.E703A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1553665500, CD093700, COSV51623426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSL3 | c.1550C>T p.P517L (on ENST00000312196 / NM_078629.4; = p.P351L on NM_006800.4) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1192308531, COSV56495482; called by muse, mutect2, varscan2
- NR1H3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs556085486, COSV68008777; called by muse, mutect2, varscan2
- NRCAM | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs368773637; called by muse, mutect2, varscan2
- OGDH | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56055812; called by muse, mutect2, varscan2
- OR4A16 | c.347T>C p.M116T | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59042967, COSV59044793; called by muse, mutect2, varscan2
- PCDHA10 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV56509905, COSV56538383; called by muse, mutect2, varscan2
- PCDHGB5 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53911923; called by muse, mutect2, varscan2
- PLXNA4 | c.2788G>A p.V930M | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs141839043, COSV58154821; called by muse, mutect2, varscan2
- PNPT1 | c.1019T>A p.F340Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as COSV53179570; called by muse, mutect2, varscan2
- PRKD1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1181038822, COSV59582684; called by muse, mutect2, varscan2
- RAD51B | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV66853632; called by muse, mutect2, varscan2
- RAD54B | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV60254191; called by muse, varscan2
- RARG | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs141058411; called by muse, mutect2, varscan2
- RBM33 | c.1484G>T p.S495I | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV56636531; called by muse, mutect2
- RPH3A | c.712G>A p.E238K (on ENST00000389385 / NM_001143854.2; = p.E234K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.981); catalogued as rs140680955; called by muse, mutect2
- RYR1 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs775455157, COSV62089184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3PXD2A | c.3041G>A p.R1014Q (on ENST00000369774 / NM_001365079.1; = p.R986Q on NM_014631.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs766002032, COSV60120125; called by muse, mutect2, varscan2
- SLC26A7 | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52602956; called by muse, mutect2, varscan2
- SLC7A3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs149506381, COSV53227102; called by muse, mutect2, varscan2
- SORCS1 | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.914); catalogued as rs150967356, COSV53884334; called by muse, mutect2, varscan2
- STS | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54271167; called by muse, mutect2, varscan2
- SUPT6H | c.1917T>G p.Y639* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV58930783; called by muse, mutect2, varscan2
- SYPL1 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV50579378; called by muse, mutect2, varscan2
- TAS2R13 | c.179G>C p.W60S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66831702, COSV66831859; called by muse, mutect2, varscan2
- TDRD5 | c.2662G>T p.A888S | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV54249018; called by muse, mutect2, varscan2
- TMEM183A | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV65888080; called by muse, mutect2, varscan2
- TNS1 | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs115718079; called by muse, mutect2, varscan2
- TTN | c.1981G>C p.V661L (on ENST00000591111; = p.V615L on NM_003319.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | PolyPhen benign (0.104); catalogued as COSV60288385; called by muse, mutect2, varscan2
- TUT7 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs776184649, COSV52898312; called by muse, mutect2, varscan2
- USP4 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV55539978; called by muse, mutect2, varscan2
- USP40 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52487181; called by muse, mutect2, varscan2
- XIRP1 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs746660526, COSV61140547; called by muse, mutect2
- ZNF433 | c.47T>C p.F16S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61400129; called by muse, mutect2, varscan2
- ZNF607 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs775221607, COSV62205789; called by muse, varscan2
- ZNF804B | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs775080121, COSV60828258; called by muse, mutect2, varscan2
- ZNF835 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0.142); catalogued as rs1476517476, COSV73379706; called by muse, mutect2, varscan2
- ATAD2B | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CKAP5 | c.4519C>A p.Q1507K | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- ENPP1 | c.1540T>G p.L514V | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- IP6K2 | c.780+1G>A p.X260_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- NRIP1 | c.1086dup p.K363* | Frame Shift Ins (INS) | VAF 84/293 reads (29%) | called by mutect2, pindel, varscan2
- RANBP17 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- RANBP2 | c.6767dup p.N2256Kfs*7 | Frame Shift Ins (INS) | VAF 179/556 reads (32%) | called by mutect2, pindel, varscan2
- TENM1 | c.6758T>G p.L2253R | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, mutect2
- TMEM128 | c.269T>A p.L90H (on ENST00000382753 / NM_001297552.2; = p.L66H on NM_032927.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.8); called by muse, mutect2
- TRPM6 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.12734C>A p.S4245Y (on ENST00000591111; = p.S4199Y on NM_003319.4) | Missense Mutation (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- ZMYM4 | c.2129del p.F710Sfs*13 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- ZNF778 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ABCA4 | c.5631G>A p.K1877= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64676994; called by muse, mutect2, varscan2
- ANLN | c.2058T>C p.R686= | Silent (SNP) | VAF 114/219 reads (52%) | catalogued as COSV56078894; called by muse, mutect2, varscan2
- ARHGEF10 | c.1221C>T p.I407= (on ENST00000398564; = p.I382= on NM_014629.4) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV50671493; called by muse, mutect2, varscan2
- C2CD3 | c.5793G>C p.G1931= | Silent (SNP) | VAF 85/215 reads (40%) | catalogued as COSV58099182; called by muse, mutect2, varscan2
- C6orf118 | c.1101G>A p.Q367= | Silent (SNP) | VAF 129/353 reads (37%) | catalogued as COSV57818238; called by muse, mutect2, varscan2
- CCDC144A | c.3657C>T p.L1219= | Silent (SNP) | VAF 42/244 reads (17%) | catalogued as COSV60701258; called by muse, mutect2, varscan2
- CHD9 | c.3669C>T p.Y1223= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs760617616, COSV54615266; called by muse, mutect2, varscan2
- CRISPLD1 | c.909C>T p.C303= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV51552335; called by muse, mutect2, varscan2
- CTNNA3 | c.2613C>T p.V871= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as COSV65528751; called by muse, mutect2, varscan2
- CUBN | c.2067G>A p.Q689= | Silent (SNP) | VAF 23/233 reads (10%) | catalogued as rs1408519313; called by muse, mutect2
- DBR1 | c.933G>T p.L311= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV53430972; called by muse, mutect2, varscan2
- DMP1 | c.1332C>T p.S444= | Silent (SNP) | VAF 102/236 reads (43%) | catalogued as rs375513808; called by muse, mutect2, varscan2
- DNAH9 | c.10902C>T p.F3634= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV52332724, COSV52371988; called by muse, mutect2, varscan2
- EREG | c.439C>A p.R147= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs376236920, COSV55262382; called by muse, mutect2, varscan2
- EVC2 | c.2097G>C p.T699= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV60400962; called by muse, mutect2, varscan2
- FASLG | c.51C>T p.S17= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV60680831; called by muse, mutect2, varscan2
- FAT3 | c.1854A>T p.G618= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV53162511; called by muse, mutect2, varscan2
- FDPS | c.384G>A p.L128= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- HSP90B1 | c.2037G>A p.A679= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs767649536, COSV55357506; called by muse, mutect2, varscan2
- NOS1AP | c.1113C>A p.S371= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV62639277; called by muse, mutect2, varscan2
- NUDT7 | c.486C>T p.Y162= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV51746825, COSV51746893; called by muse, mutect2, varscan2
- NXF1 | c.1644C>T p.F548= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs201533876, COSV53675222; called by muse, mutect2, varscan2
- OR1L4 | c.30C>A p.T10= | Silent (SNP) | VAF 96/290 reads (33%) | catalogued as COSV52341339; called by muse, mutect2, varscan2
- OR8H2 | c.666C>G p.L222= | Silent (SNP) | VAF 117/386 reads (30%) | catalogued as COSV57947062; called by muse, mutect2, varscan2
- PM20D2 | c.780A>T p.V260= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV51531865; called by muse, mutect2, varscan2
- SGK3 | c.63C>A p.S21= | Silent (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- SYT14 | c.1116A>G p.Q372= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV55062170; called by muse, mutect2, varscan2
- TTN | c.45003T>A p.P15001= (on ENST00000591111; = p.P7577= on NM_003319.4) | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV60288361; called by muse, mutect2, varscan2
- WEE2 | c.1149C>T p.H383= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs757584609, COSV66879933; called by muse, mutect2, varscan2
- CASR | c.1378-6142G>A | Intron (SNP) | VAF 52/142 reads (37%) | catalogued as rs866241407, COSV56138761; called by muse, mutect2, varscan2
- FOXP1 | c.181-17869_181-17868insG | Intron (INS) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- FRMPD2B | n.474C>A | RNA (SNP) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- KALRN | c.4929+22034C>A | Intron (SNP) | VAF 27/74 reads (36%) | catalogued as COSV53777261; called by muse, mutect2, varscan2
- PARGP1 | n.520A>G | RNA (SNP) | VAF 61/351 reads (17%) | called by muse, mutect2, varscan2
